Somatic mutation profile of tumor specimen TCGA-62-A46S-01A (aliquot TCGA-62-A46S-01A-11D-A24D-08) from TCGA case TCGA-62-A46S, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.4 years (26,825 days).
Specimen TCGA-62-A46S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 567aae04-131f-4f4f-9c0c-080c0971d931.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-A46S-10A (Blood Derived Normal), aliquot TCGA-62-A46S-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28689bdd-855b-43f4-b8da-fc625b8321a9

The open-access MAF lists 129 somatic variants for this specimen: 98 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 27, Nonsense Mutation 6, Splice Site 5, Frame Shift Del 3, Intron 1, 3'UTR 1, Splice Region 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLB1 | c.442C>A p.R148S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs192732174, CM000711, CM056963, COSV56568961; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCB9 | c.1738C>T p.R580C (on ENST00000280560 / NM_019625.4; = p.R537C on NM_019624.3) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs1286766702, COSV99757496; called by muse, mutect2, varscan2
- ACTL8 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as rs1304594827, COSV100958462; called by muse, mutect2, varscan2
- ADCY5 | c.2908T>C p.F970L | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100567188; called by muse, mutect2, varscan2
- ADD3 | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV99523093; called by muse, mutect2, varscan2
- ADGRG4 | c.5285C>T p.S1762F | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99794078; called by muse, mutect2, varscan2
- AHCTF1 | c.2407A>T p.T803S (on ENST00000366508; = p.T777S on NM_015446.5) | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV100402977; called by muse, mutect2, varscan2
- ANXA3 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99363453; called by muse, mutect2
- ATP1A1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV99814070; called by muse, mutect2
- BRCA2 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV101203827; called by muse, mutect2
- BRCA2 | c.5054C>T p.S1685L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV101203829; called by muse, mutect2, varscan2
- BRINP3 | c.237-1G>T p.X79_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100818132; called by muse, mutect2
- C2CD3 | c.3301G>T p.G1101C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100486133; called by muse, mutect2, varscan2
- CACNA1A | c.1101G>T p.R367S | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV100800320, COSV64192706; called by muse, mutect2, varscan2
- CARMIL3 | c.2885C>T p.S962F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV100549097, COSV100549431; called by muse, mutect2, varscan2
- CDH11 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99216837; called by muse, mutect2, varscan2
- CECR2 | c.1979G>A p.R660Q (on ENST00000342247 / NM_001290047.2; = p.R477Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs371979990; called by muse, mutect2, varscan2
- CEP170B | c.716A>T p.Q239L (on ENST00000453495; = p.Q168L on NM_015005.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101371370; called by muse, mutect2, varscan2
- CRLF2 | c.530C>A p.A177D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.45); catalogued as rs756423580, COSV101053569; called by muse, mutect2
- DCLRE1A | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV63748246; called by muse, mutect2, varscan2
- DHRS7C | c.188G>T p.R63M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100364507; called by muse, mutect2, varscan2
- DNAH5 | c.6777G>T p.M2259I | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54238912; called by muse, mutect2
- DNAJB5 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs1434198650, COSV56627555; called by muse, mutect2
- DNM1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs772314897, COSV57854308; called by muse, mutect2, varscan2
- DYNC1H1 | c.7676C>T p.T2559M | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1324450395, COSV64139540; called by muse, mutect2
- EPHB3 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as COSV100382727, COSV100383019; called by muse, mutect2, varscan2
- ESRRG | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs773155899, COSV100752149; called by muse, mutect2, varscan2
- FABP4 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 180/266 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99808454; called by muse, mutect2, varscan2
- FAM124A | c.1036C>T p.R346* (on ENST00000322475 / NM_001242312.2; = p.R382* on NM_145019.4) | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs201443401, COSV99696093; called by mutect2, varscan2
- FRZB | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99717228; called by muse, mutect2, varscan2
- GANAB | c.2222A>T p.N741I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV100647760; called by muse, mutect2, varscan2
- GLRB | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.058); catalogued as COSV52421287; called by muse, mutect2
- GNLY | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.834); catalogued as COSV99808839; called by muse, mutect2, varscan2
- GPATCH8 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100132393; called by muse, mutect2, varscan2
- GPR148 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as COSV59309317; called by muse, mutect2, varscan2
- GRIK4 | c.1145C>G p.T382R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV101483370; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2534A>T p.D845V (on ENST00000265755 / NM_016328.3; = p.D830V on NM_005685.4) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99733873; called by muse, mutect2, varscan2
- INO80 | c.3182G>T p.W1061L | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV100731490; called by muse, mutect2
- IRX1 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100116143; called by muse, mutect2, varscan2
- KIF16B | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756519206, COSV100733604; called by muse, mutect2, varscan2
- KIR2DL4 | c.263T>C p.L88P (on ENST00000396284; = p.L49P on NM_001080770.2) | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610468; called by muse, mutect2, varscan2
- KMT2A | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100627644; called by muse, mutect2, varscan2
- LRFN5 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.145); catalogued as COSV53246426, COSV99982062, COSV99984147; called by muse, mutect2, varscan2
- MCAM | c.611T>C p.L204S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs753825047, COSV99875296; called by muse, mutect2, varscan2
- MDH1B | c.977G>T p.R326M | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV65591262; called by muse, mutect2, varscan2
- MUC16 | c.13109G>A p.S4370N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs565608680, COSV101197450, COSV67493596; called by muse, mutect2, varscan2
- MYCBP2 | c.11258A>G p.N3753S (on ENST00000357337; = p.N3791S on NM_015057.5) | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.931); catalogued as rs751007875, COSV100628923; called by muse, mutect2, varscan2
- MYL9 | c.131A>T p.N44I | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99640916; called by muse, mutect2
- MYO3B | c.2961C>A p.S987R | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100508919; called by muse, mutect2, varscan2
- NALCN | c.1235G>T p.R412M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as COSV99212674; called by muse, mutect2, varscan2
- NAV3 | c.5297+1G>A p.X1766_splice | Splice Site (SNP) | VAF 6/88 reads (7%) | catalogued as COSV57090094, COSV99893652; called by muse, mutect2
- NECTIN1 | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV50603131, COSV99871670; called by muse, mutect2, varscan2
- NF1 | c.1722-1G>C p.X574_splice | Splice Site (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100645805, COSV62206465; called by mutect2, varscan2
- NLRP9 | c.2839C>A p.L947M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100242435; called by muse, mutect2, varscan2
- NUMA1 | c.5617T>G p.L1873V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99474422; called by muse, varscan2
- OR12D2 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101011214, COSV65827861; called by mutect2, varscan2
- OR4K2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT tolerated (0.56); PolyPhen probably damaging (1); catalogued as rs141210026, COSV100063939; called by muse, mutect2, varscan2
- OR5D18 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs566365669, COSV61736850, COSV61737947; called by muse, mutect2, varscan2
- OR6Q1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 41/188 reads (22%) | catalogued as rs369989982; called by muse, mutect2, varscan2
- PAPPA | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs778367669, COSV100072590; called by muse, mutect2, varscan2
- PCDHGB2 | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768644219, COSV99528612; called by muse, mutect2, varscan2
- PCSK1 | c.860C>A p.A287D | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226746; called by muse, mutect2, varscan2
- PKP2 | c.1971+2T>A p.X657_splice | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99297085; called by muse, mutect2, varscan2
- PLCB2 | c.1660C>A p.Q554K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV99541365; called by muse, mutect2, varscan2
- PRCP | c.952G>T p.V318L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100475524; called by muse, mutect2, varscan2
- RASIP1 | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99710403; called by muse, mutect2, varscan2
- RELN | c.9444A>G p.R3148= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as rs1277733317, COSV100631963; called by muse, mutect2, varscan2
- SARS2 | c.170A>C p.Q57P | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV99671044; called by muse, mutect2
- SLC3A1 | c.1871C>T p.T624I | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs745773702, COSV99575852; called by muse, mutect2, varscan2
- SLFN13 | c.1993A>T p.I665F | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99539634; called by muse, mutect2, varscan2
- SLITRK5 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100280116, COSV100280154; called by muse, mutect2, varscan2
- SORCS3 | c.2071A>G p.I691V | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs759528902, COSV100863347; called by muse, mutect2, varscan2
- STK11 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100479383, COSV58820651; called by muse, mutect2, varscan2
- STPG2 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 35/120 reads (29%) | catalogued as COSV99757608; called by muse, mutect2, varscan2
- THOC6 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs756027209, COSV99560344; called by muse, mutect2, varscan2
- THSD7A | c.575A>T p.Q192L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV101448502; called by muse, mutect2, varscan2
- TRAPPC12 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.632); catalogued as COSV60848954; called by muse, mutect2, varscan2
- TRIM9 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs761319285, COSV53613827, COSV53617393; called by muse, mutect2, varscan2
- TRMO | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as COSV100795989; called by muse, mutect2, varscan2
- UNC50 | c.465T>A p.Y155* | Nonsense Mutation (SNP) | VAF 48/121 reads (40%) | catalogued as COSV99383852; called by muse, mutect2, varscan2
- USP29 | c.2004G>T p.K668N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV99517517; called by muse, mutect2, varscan2
- UTP18 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV99834598; called by muse, mutect2
- XRRA1 | c.1808G>C p.R603P | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100213081; called by muse, mutect2, varscan2
- ZBTB12 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV100976934, COSV64993795; called by muse, mutect2, varscan2
- ZNF16 | c.1946G>T p.R649M | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1368534818, COSV99429356; called by muse, mutect2
- ZNF229 | c.2432T>A p.L811Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349912; called by muse, mutect2, varscan2
- ZNF274 | c.1144G>A p.V382M (on ENST00000610905; = p.V277M on NM_016324.3) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs879153442, COSV100464604; called by muse, mutect2, varscan2
- ZNF283 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV61032397; called by muse, mutect2, varscan2
- ZNF335 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773031524, COSV100532537; called by mutect2, varscan2
- ZNF676 | c.1561T>A p.F521I (on ENST00000650058; = p.F489I on NM_001001411.3) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as COSV101236073; called by muse, mutect2, varscan2
- ZNF800 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV99757558; called by muse, mutect2, varscan2
- COL7A1 | c.6280-1G>A p.X2094_splice | Splice Site (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- KLK8 | c.748del p.D250Tfs*7 | Frame Shift Del (DEL) | VAF 42/192 reads (22%) | called by mutect2, pindel, varscan2
- NAA15 | c.823_832del p.E275Kfs*21 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- PRAMEF6 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by mutect2, varscan2
- ZAN | c.7462del p.Q2488Rfs*12 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- ZNF658 | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ABCA1 | c.5277G>C p.V1759= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV101036355; called by muse, mutect2, varscan2
- BCL11A | c.2097C>T p.P699= (on ENST00000335712 / NM_001365609.1; = p.P733= on NM_018014.4) | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs1209098022, COSV100184584; called by muse, mutect2, varscan2
- BRCA2 | c.4755C>T p.I1585= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as COSV101203828; called by muse, mutect2, varscan2
- CRLF2 | c.531C>A p.A177= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV101053567; called by muse, mutect2
- DOCK2 | c.4857C>A p.V1619= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99909615; called by muse, mutect2, varscan2
- DOCK2 | c.4858C>A p.R1620= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs142830212, COSV99914245; called by muse, mutect2, varscan2
- EP400 | c.3372A>G p.K1124= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100200102; called by muse, mutect2, varscan2
- HHAT | c.1059A>T p.P353= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV99802038; called by muse, mutect2, varscan2
- LCMT2 | c.567G>C p.A189= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99979868; called by muse, mutect2, varscan2
- MAST1 | c.570T>A p.T190= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as COSV99262063; called by muse, mutect2, varscan2
- MOS | c.414C>A p.I138= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV100322682; called by muse, mutect2
- MRPL43 | c.183C>T p.V61= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99271748; called by muse, mutect2, varscan2
- MTUS2 | c.399G>T p.S133= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV101462030, COSV70923212; called by muse, mutect2, varscan2
- OR12D2 | c.315G>T p.L105= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV101011056; called by mutect2, varscan2
- OR5D16 | c.576T>C p.P192= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV101003800, COSV65721745; called by muse, mutect2
- PCDHB6 | c.900G>T p.R300= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV99169880; called by muse, mutect2, varscan2
- PCDHGA6 | c.1680C>A p.P560= | Silent (SNP) | VAF 83/276 reads (30%) | catalogued as COSV53898426, COSV99528614; called by muse, mutect2, varscan2
- PCDHGA9 | c.180G>T p.A60= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV53954357, COSV53956703, COSV99528618; called by muse, mutect2, varscan2
- PCLO | c.5847G>A p.G1949= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs1223703765, COSV100426380; called by muse, mutect2, varscan2
- RXFP3 | c.840G>T p.L280= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100347183; called by muse, mutect2
- SRCAP | c.5457G>A p.Q1819= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV99348951; called by muse, mutect2
- TEX264 | c.618G>T p.V206= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV100392430; called by muse, mutect2, varscan2
- TLK2 | c.339A>G p.Q113= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100408577; called by muse, mutect2, varscan2
- TRMT2B | c.1041C>T p.I347= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100105098; called by muse, mutect2, varscan2
- USH2A | c.1479C>T p.Y493= | Silent (SNP) | VAF 57/184 reads (31%) | catalogued as COSV100227775; called by muse, mutect2, varscan2
- ZNF160 | c.1476A>G p.Q492= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as rs748286121, COSV100762199; called by muse, mutect2, varscan2
- ZNF777 | c.717C>T p.V239= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as rs370235914; called by muse, mutect2, varscan2
- ANK2 | c.84+57069T>C | Intron (SNP) | VAF 13/42 reads (31%) | catalogued as rs774481038; called by muse, mutect2, varscan2
- B2M | c.-2A>T | 5'UTR (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100837527; called by muse, mutect2, varscan2
- KIR3DX1 | n.98C>T | RNA (SNP) | VAF 28/81 reads (35%) | catalogued as COSV99682793; called by muse, mutect2, varscan2
- NPR3 | c.*3200T>A | 3'UTR (SNP) | VAF 34/136 reads (25%) | catalogued as COSV99421996; called by muse, mutect2, varscan2
